Somatic mutation profile of tumor specimen MMRF_1153_1_BM_CD138pos (aliquot MMRF_1153_1_BM_CD138pos_T2_KHS5U_L15098) from MMRF case MMRF_1153, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.5 years (21,734 days).
Specimen MMRF_1153_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48639871-d4be-4c8e-9d0a-f2865835eaf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1153_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1153_1_PB_Whole_C1_KHS5U_L15097; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/537ae33f-b37d-49f6-a8db-b17e54883e31

The open-access MAF lists 158 somatic variants for this specimen: 50 protein-altering or splice-affecting, 23 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 54, Missense Mutation 40, Silent 23, Intron 16, 5'UTR 6, 5'Flank 4, Nonsense Mutation 4, RNA 4, Splice Site 3, Frame Shift Del 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 40/480 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RB1 | c.2325+1G>A p.X775_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as rs1131690882, CS058012, COSV57302937, COSV57317467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGBL3 | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV99311756; called by muse, mutect2
- AHNAK2 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs372753892; called by muse, mutect2, varscan2
- CSMD2 | c.7684C>T p.H2562Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs1332745877, COSV53961315; called by muse, mutect2
- FAHD2A | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764829445; called by muse, mutect2, varscan2
- GIMAP4 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs778127185, COSV55432328; called by muse, mutect2, varscan2
- GOLGA4 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs766902144; called by muse, mutect2, varscan2
- IGHD6-25 | c.16T>G p.Y6D | Missense Mutation (SNP) | VAF 98/102 reads (96%) | catalogued as rs547697920; called by muse, varscan2
- KCNMA1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs202213336, COSV54259922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARS2 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs1264838638; called by muse, mutect2, varscan2
- OR5M8 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 72/195 reads (37%) | catalogued as COSV59116574; called by muse, mutect2, varscan2
- RC3H1 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1160795981; called by muse, mutect2, varscan2
- SLC18A3 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV104400862; called by muse, mutect2, varscan2
- TDRD12 | c.1533G>T p.L511F | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1473477401; called by muse, mutect2, varscan2
- TRAPPC10 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs937562044; called by muse, mutect2, varscan2
- TSR3 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575767980, COSV50105506, COSV50105649; called by mutect2, varscan2
- UBTD2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 15/347 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1435991882; called by muse, mutect2
- ZFHX3 | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.044); catalogued as rs1397685131, COSV51723999; called by muse, mutect2, varscan2
- ZNF423 | c.88G>A p.V30M (on ENST00000563137 / NM_001379286.1; = p.V22M on NM_015069.4) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.197); catalogued as rs778893500, COSV99284228; called by muse, mutect2, varscan2
- AC092032.2 | n.67+1G>A | Splice Site (SNP) | VAF 186/297 reads (63%) | called by muse, mutect2, varscan2
- AP3B1 | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD226 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CD83 | c.105C>G p.C35W | Missense Mutation (SNP) | VAF 158/246 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CDH12 | c.1103C>A p.T368K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CHD9 | c.3665+3A>G | Splice Region (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- CHST10 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSTF2 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- EPHA3 | c.2755T>A p.W919R | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM161A | c.1633A>T p.R545* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- HIVEP2 | c.6037A>G p.K2013E | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNMT | c.811T>A p.F271I | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2
- HTR3C | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, varscan2
- KDM4B | c.2998_3000del p.S1000del | In Frame Del (DEL) | VAF 97/338 reads (29%) | called by pindel, varscan2
- KRTAP9-2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LDLRAD3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUM | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 121/265 reads (46%) | called by muse, mutect2, varscan2
- MUC19 | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPHP3 | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PCDHA8 | c.2111_2133del p.I704Sfs*18 | Frame Shift Del (DEL) | VAF 28/318 reads (9%) | called by mutect2, pindel
- PCLO | c.3350G>A p.G1117E | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PDE7B | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- SHPRH | c.439A>G p.N147D | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SLC25A21 | c.439-1G>T p.X147_splice | Splice Site (SNP) | VAF 86/178 reads (48%) | called by muse, mutect2, varscan2
- SNCAIP | c.650A>T p.H217L | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF347 | c.964T>C p.C322R | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF502 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZSCAN9 | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- AC104452.1 | c.879C>T p.G293= | Silent (SNP) | VAF 29/385 reads (8%) | catalogued as rs759245586; called by muse, mutect2
- ADAMTSL1 | c.528G>A p.G176= | Silent (SNP) | VAF 56/159 reads (35%) | called by muse, mutect2, varscan2
- AXL | c.2040G>A p.L680= (on ENST00000301178 / NM_021913.5; = p.L671= on NM_001699.6) | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- BMP15 | c.684C>T p.D228= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- CDH6 | c.1455C>A p.A485= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV54068501; called by muse, mutect2
- CLEC18C | c.372C>A p.V124= | Silent (SNP) | VAF 31/278 reads (11%) | called by muse, mutect2, varscan2
- HTR7 | c.1210C>A p.R404= | Silent (SNP) | VAF 57/150 reads (38%) | catalogued as COSV99519229; called by muse, mutect2, varscan2
- IGHV1-69D | c.219C>A p.I73= | Silent (SNP) | VAF 92/119 reads (77%) | called by muse, mutect2, varscan2
- IL6ST | c.1545A>G p.K515= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- NRK | c.738T>C p.T246= | Silent (SNP) | VAF 55/56 reads (98%) | called by muse, mutect2, varscan2
- OTOG | c.8268C>T p.C2756= | Silent (SNP) | VAF 48/237 reads (20%) | catalogued as rs867232792; called by muse, mutect2, varscan2
- P3H2 | c.663T>C p.Y221= | Silent (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- POLA2 | c.1524C>T p.Y508= | Silent (SNP) | VAF 32/230 reads (14%) | called by muse, mutect2, varscan2
- POU1F1 | c.349T>C p.L117= | Silent (SNP) | VAF 47/177 reads (27%) | catalogued as COSV60155626; called by muse, mutect2, varscan2
- PRDX4 | c.363A>G p.T121= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, varscan2
- PRPSAP1 | c.1107C>T p.H369= | Silent (SNP) | VAF 88/206 reads (43%) | called by muse, mutect2, varscan2
- SCN9A | c.4185T>G p.G1395= (on ENST00000303354; = p.G1384= on NM_002977.3) | Silent (SNP) | VAF 93/181 reads (51%) | called by muse, mutect2, varscan2
- SDK1 | c.1509G>A p.V503= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- SIGLEC8 | c.558C>T p.P186= | Silent (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- SYN2 | c.1071G>A p.V357= | Silent (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- ZEB2 | c.2409A>C p.P803= | Silent (SNP) | VAF 59/132 reads (45%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.789T>C p.N263= | Silent (SNP) | VAF 64/204 reads (31%) | called by muse, mutect2, varscan2
- ZNF32 | c.186G>A p.S62= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs776162310; called by muse, mutect2, varscan2
- ABHD18 | c.*1353G>A | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- AC116366.2 | c.-637-15748A>T | Intron (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- AC124067.4 | n.1638A>G | RNA (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- AKR1B10 | c.*245C>A | 3'UTR (SNP) | VAF 50/274 reads (18%) | called by muse, mutect2, varscan2
- APH1B | c.*1863G>T | 3'UTR (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- CD300A | c.*19C>T | 3'UTR (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- CD46 | c.-81C>T | 5'UTR (SNP) | VAF 107/280 reads (38%) | called by muse, mutect2, varscan2
- CDS2 | c.*2880G>A | 3'UTR (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- CHORDC1 | c.329+151T>C | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, varscan2
- COL6A2 | c.2462-2342C>T | Intron (SNP) | VAF 24/55 reads (44%) | catalogued as rs1380994726; called by muse, mutect2, varscan2
- CREB3L2 | c.*3626C>T | 3'UTR (SNP) | VAF 44/188 reads (23%) | called by muse, mutect2, varscan2
- CSNK1A1P1 | n.165C>T | RNA (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- CXADR | c.*4241A>G | 3'UTR (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- CYYR1 | c.*1271A>G | 3'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- DCC | c.*2522A>T | 3'UTR (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- DCDC2 | c.923-50C>T | Intron (SNP) | VAF 26/448 reads (6%) | catalogued as rs1282247897, COSV101015344; called by muse, mutect2
- DIAPH2 | c.*2370del | 3'UTR (DEL) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- DIRAS2 | c.*2716A>C | 3'UTR (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- EIF2S1 | c.321+21A>T | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- ENOX2 | c.*1824G>T | 3'UTR (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- EPC1 | chr10:32268594 A>G | 3'Flank (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- FBN2 | c.4471+431G>T | Intron (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- FBXL20 | c.*6967A>C | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- FKBP10 | c.*656G>A | 3'UTR (SNP) | VAF 31/111 reads (28%) | catalogued as rs1218534862; called by muse, mutect2, varscan2
- FYCO1 | c.*1986A>C | 3'UTR (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- GABRP | c.*1171T>A | 3'UTR (SNP) | VAF 55/281 reads (20%) | called by muse, mutect2, varscan2
- GNAQ | c.*3812T>C | 3'UTR (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- GRPEL2 | c.*208T>C | 3'UTR (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- IFT81 | c.1645-95C>G | Intron (SNP) | VAF 28/248 reads (11%) | called by muse, varscan2
- IGHV5-51 | c.-23T>C | 5'UTR (SNP) | VAF 72/134 reads (54%) | catalogued as rs557025310; called by muse, varscan2
- IPO5 | c.3065+128A>C | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- LIN28B | c.*1278T>G | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- LIX1 | c.*1464A>G | 3'UTR (SNP) | VAF 7/54 reads (13%) | catalogued as rs1425860411; called by muse, mutect2, varscan2
- MAP3K21 | c.*780C>T | 3'UTR (SNP) | VAF 9/73 reads (12%) | catalogued as rs1306168272; called by muse, mutect2, varscan2
- MAP3K21 | c.*1296T>A | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- MAST4 | c.*120T>C | 3'UTR (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- MBL2 | c.*630G>A | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- MFAP3L | c.298+404G>C | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- MMP1 | c.-58A>C | 5'UTR (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- MRNIP | c.538-85A>T | Intron (SNP) | VAF 35/127 reads (28%) | called by muse, mutect2, varscan2
- MTG1 | c.573+234_573+236del | Intron (DEL) | VAF 14/35 reads (40%) | called by pindel, varscan2
- MTR | c.*537A>G | 3'UTR (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- MTREX | c.*731C>A | 3'UTR (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- NCOA3 | c.*824T>A | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- NOC2LP2 | n.1338G>A | RNA (SNP) | VAF 50/100 reads (50%) | catalogued as rs754491024; called by muse, mutect2, varscan2
- PDE4DIP | c.2815+5078A>G | Intron (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- PDLIM3 | c.94-8869G>C | Intron (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- PGM3 | c.*2612T>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- PLA2G2D | chr1:20119558 C>G | 5'Flank (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- PLCB1 | c.*751C>A | 3'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- PPP1R12A | c.*1A>T | 3'UTR (SNP) | VAF 25/119 reads (21%) | catalogued as rs1161432380; called by muse, mutect2, varscan2
- PPP1R3C | c.*81C>A | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*2770G>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- RARRES2P7 | n.19T>C | RNA (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- RB1CC1 | c.-508C>T | 5'UTR (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- RBAK | c.*1249C>G | 3'UTR (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- RHOB | c.*604C>T | 3'UTR (SNP) | VAF 123/266 reads (46%) | called by muse, mutect2, varscan2
- ROBO1 | c.*1374G>T | 3'UTR (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- RTL6 | c.-139C>T | 5'UTR (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- SAYSD1 | c.*211_*212dup | 3'UTR (INS) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- SENP2 | chr3:185582569 C>A | 5'Flank (SNP) | VAF 21/338 reads (6%) | called by muse, mutect2
- SEPTIN8 | c.1287-2226G>T | Intron (SNP) | VAF 14/122 reads (11%) | called by mutect2, varscan2
- SERPINB8 | c.*1418A>T | 3'UTR (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- SH2D1B | c.*1489A>T | 3'UTR (SNP) | VAF 13/149 reads (9%) | called by muse, mutect2
- SH2D1B | c.*1488G>C | 3'UTR (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- SH3TC2 | c.1178-20A>C | Intron (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- SLC39A8 | c.*1983G>T | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*1592C>T | 3'UTR (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*1731G>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | catalogued as rs1478974235; called by muse, mutect2, varscan2
- SOSTDC1 | c.*1016C>T | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- SPEG | c.2114-48C>T | Intron (SNP) | VAF 41/148 reads (28%) | catalogued as rs1393063610; called by muse, mutect2, varscan2
- SPOCK1 | c.*2253T>C | 3'UTR (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- SPRY2 | c.*628G>A | 3'UTR (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*4674G>A | 3'UTR (SNP) | VAF 64/131 reads (49%) | catalogued as rs565452004; called by muse, mutect2, varscan2
- SSU72 | c.*344C>T | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- ST6GAL2 | c.*4961A>G | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*225C>T | 3'UTR (SNP) | VAF 10/64 reads (16%) | catalogued as rs1181845169; called by muse, mutect2, varscan2
- TAS2R20 | c.*196T>C | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- TCEAL9 | c.*195A>T | 3'UTR (SNP) | VAF 25/25 reads (100%) | catalogued as COSV101012037; called by muse, mutect2, varscan2
- TIAL1 | chr10:119596540 G>A | 5'Flank (SNP) | VAF 10/20 reads (50%) | catalogued as rs1216244576; called by muse, mutect2, varscan2
- TMEM132C | c.*862A>G | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- TMEM258 | c.-20A>G | 5'UTR (SNP) | VAF 119/376 reads (32%) | catalogued as rs947740651; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975348 G>A | 5'Flank (SNP) | VAF 85/88 reads (97%) | called by muse, mutect2, varscan2
- YTHDF1 | c.*184_*198del | 3'UTR (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- ZC3H14 | c.*5269G>A | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
